Somatic mutation profile of tumor specimen 0DKFA3 from CCDI case PBBYEA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.5 years (926 days).
Specimen 0DKFA3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bcfb3aa7-150d-4e90-9ecd-878556e97143.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DKF9P (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3dc47c24-d315-4574-a3ef-728e61671ae0

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- THSD7A | c.2006C>T p.A669V | Missense Mutation (SNP) | VAF 123/817 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.366); catalogued as rs765150649, COSV101448907, COSV70261202; called by muse, mutect2, varscan2
- PSMA5 | c.291+72G>A | Intron (SNP) | VAF 9/84 reads (11%) | called by muse, varscan2
